Somatic mutation profile of tumor specimen TCGA-4X-A9FA-01A (aliquot TCGA-4X-A9FA-01A-11D-A423-09) from TCGA case TCGA-4X-A9FA, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type A, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 52.1 years (19,032 days).
Specimen TCGA-4X-A9FA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 01fb72b6-fa09-4989-a1a0-8d4862843e6c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4X-A9FA-10A (Blood Derived Normal), aliquot TCGA-4X-A9FA-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a06837dc-feaa-49fc-8f35-1b88318b87f9

The open-access MAF lists 13 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 11, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 147/444 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2, varscan2
- COL6A6 | c.4504C>T p.R1502C | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.353); catalogued as rs764994836, COSV62023950; called by muse, mutect2, varscan2
- UNC13B | c.1777G>C p.D593H | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV65938393; called by muse, mutect2, varscan2
- APOB | c.8114G>C p.R2705T | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT tolerated (0.57); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ARHGAP5 | c.3432T>G p.S1144R | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- DLG5 | c.571C>G p.L191V | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GPR32 | c.1045C>T p.P349S | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.019); called by muse, mutect2
- KIAA0825 | c.323A>T p.Q108L | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2
- TMEM139 | c.112G>T p.V38F | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.442); called by muse, mutect2, varscan2
- TMEM63B | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TNIP2 | c.385A>C p.S129R | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CPED1 | c.1341C>T p.S447= | Silent (SNP) | VAF 3/40 reads (8%) | catalogued as COSV100120343; called by muse, mutect2
- RIN1 | c.1482A>G p.Q494= | Silent (SNP) | VAF 10/52 reads (19%) | called by muse, mutect2, varscan2
